Somatic mutation profile of tumor specimen TARGET-40-NAASJK-01A (aliquot TARGET-40-NAASJK-01A-01D) from TARGET case TARGET-40-NAASJK, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 15.2 years (5,540 days).
Specimen TARGET-40-NAASJK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e12457f-bbec-4443-8755-64e155332fd2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAASJK-10A (Blood Derived Normal), aliquot TARGET-40-NAASJK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f441bced-372e-4d9c-b2d3-69248612d518

The open-access MAF lists 19 somatic variants for this specimen: 9 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 6, RNA 2, 5'UTR 1, Nonsense Mutation 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH9 | c.8154G>C p.K2718N | Missense Mutation (SNP) | VAF 14/261 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99306917; called by muse, mutect2
- FLNC | c.7561G>A p.G2521S | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs746969946; called by muse, mutect2, varscan2
- FLT4 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs368167894; called by muse, mutect2
- GSTA1 | c.169A>G p.M57V | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.222); catalogued as rs1462446265; called by muse, mutect2, varscan2
- KCNS2 | c.303C>A p.F101L | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54640807; called by muse, mutect2, varscan2
- SLC18A3 | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as rs558868462, COSV60320999, COSV60330275; called by muse, mutect2, varscan2
- GIT1 | c.973C>G p.R325G | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNS2 | c.972C>A p.Y324* | Nonsense Mutation (SNP) | VAF 18/86 reads (21%) | called by muse, mutect2, varscan2
- TSPYL2 | c.1838_1839del p.F613* | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | called by mutect2, pindel
- CARD14 | c.1395C>T p.R465= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as rs759000751; called by muse, mutect2, varscan2
- IL24 | c.162C>T p.F54= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as rs970968583; called by muse, varscan2
- KCNG1 | c.351C>T p.F117= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs1269201646, COSV65368043; called by muse, mutect2, varscan2
- OR5AP2 | c.189C>A p.T63= | Silent (SNP) | VAF 22/81 reads (27%) | called by muse, mutect2, varscan2
- PARP10 | c.840C>T p.T280= | Silent (SNP) | VAF 54/113 reads (48%) | catalogued as rs1554748960, COSV100477625; called by muse, mutect2, varscan2
- SPATA5 | c.1575T>C p.N525= | Silent (SNP) | VAF 20/82 reads (24%) | called by mutect2, varscan2
- BPIFA4P | n.599C>T | RNA (SNP) | VAF 13/39 reads (33%) | called by muse, mutect2
- EPG5 | c.3240-22C>T | Intron (SNP) | VAF 8/34 reads (24%) | catalogued as rs764328731, COSV56345207; called by muse, mutect2, varscan2
- FAM110B | c.-41G>A | 5'UTR (SNP) | VAF 38/88 reads (43%) | called by muse, varscan2
- MEIS3P2 | n.204C>G | RNA (SNP) | VAF 22/275 reads (8%) | called by muse, mutect2
